Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A7DR, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A7DR-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in head, tumor is invasive of duodenum to form a mass and solid, with 3x2.5x2.2cm in size, firm and white-gray surface.

Microscopic Description: Tumor is composed of papillary glands or dilated glands containing mucin. Glands are variability in shape and size. Tumor cells are invasion of fat tissue or duodenum mucosa or pancreatic tissue. Mitotic index is present. Nuclei are hyperchromatic and very irregularly enlarged and prominent nucleoli. Cytoplasm are moderate and eosinophilic. Stroma is desmoplastic and invasion of lymphocytes.

Diagnosis Details: Mucinous non-cyst adenocarcinoma, moderately-differentiated, infiltrating fat tissue

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Head

Tumor size: 3 x 2.5 x 2.2 cm

Histologic type: Mucin-producing adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Other - Duodenum

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

CGCF ICD O-3
Carcinoma, colloid 8480/3
path
Adenocarcinoma, mucin-producing 8481/3
Site Pancreas head 0250
JP 9/4/13

HIFAA Discrepancy		✓

Source: NCI Genomic Data Commons file fc62294d-e068-4e36-abf6-dbcd6224d56e (TCGA-FB-A7DR.DEBA9632-E0F3-4D6C-836B-543E07B42612.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).